Surgical pathology report (de-identified scan), TCGA case TCGA-FZ-5920, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-FZ-5920-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: BILE DUCT, MARGIN, EXCISION -

- A. INVASIVE MODERATELY TO POORLY DIFFERENTIATED ADENOCARCINOMA (see Part 4 for final margin).
- B. PANCREATIC INTRAEPITHELIAL NEOPLASIA III (PanIN III).

PART 2: DUODENUM AND SMALL BOWEL, WHIPPLE RESECTION -

- A. INVASIVE MODERATELY TO POORLY DIFFERENTIATED DUCTAL ADENOCARCINOMA (3.5cm), ARISING IN THE PANCREATIC HEAD WITH INVASION INTO PERIPANCREATIC SOFT TISSUE.
- B. CARCINOMA IS PRESENT AT THE VASCULAR GROOVE MARGIN
- C. CARCINOMA IS PRESENT AT THE RETROPERITONEAL MARGIN.
- D. BENIGN PANCREAS RESECTION MARGIN.
- E. PERINEURAL AND ANGIOLYMPHATIC INVASION IS IDENTIFIED.
- F. THREE (3) OF NINE (9) LYMPH NODES, POSITIVE FOR CARCINOMA (3/9).
- G. PATHOLOGIC STAGE: pT3, N1b, MX (see comment).
- H. PANCREATIC INTRAEPITHELIAL NEOPLASIA III (PanIN III).
- I. CHRONIC PANCREATITIS
- J. ACUTE AND CHRONIC CHOLECYSTITIS.
- a. NO STONES IDENTIFIED.

PART 3: SMALL BOWEL, RESECTION -

- A. SMALL BOWEL WITH NO SIGNIFICANT ABNORMALITY
- B. NO TUMOR SEEN.

PART 4: BILE DUCT, "FINAL MARGIN", EXCISION -

BILE DUCT, NEGATIVE FOR CARCINOMA.

SYNOPTIC DATA - PRIMARY PANCREAS(EXOCRINE) TUMORS

----- MACROSCOPIC -----

SPECIMEN TYPE: Pylorus sparing pancreaticoduodenectomy, partial pancreatectomy
TUMOR SITE: Pancreatic head
TUMOR SIZE: Greatest dimension: 3.5 cm
Additional dimensions: 2.6 cm
OTHER ORGANS RESECTED: Gallbladder.

----- MICROSCOPIC -----

HISTOLOGIC TYPE: Ductal adenocarcinoma
HISTOLOGIC GRADE: G2
PATHOLOGIC STAGING (pTNM): pT3
pN1b
Number of lymph nodes examined: 9
Number of lymph nodes involved: 3
pMX
MARGINS: Common bile duct margin uninvolved
Pancreatic parenchymal margin uninvolved
Uncinate process/retroperitoneal margin involved
SMV/portal vein notch margin involved
Proximal duodenal/gastric margin uninvolved
Distal duodenal margin uninvolved

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

Present

PERINEURAL INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS: Pancreatic intraepithelial neoplasia (highest grade: PanIN III)

Chronic pancreatitis

Source: NCI Genomic Data Commons file b3773975-ab91-495a-a3b1-afd65dce4823 (TCGA-FZ-5920.2D642B16-7FD4-4C8E-8111-40271550FF82.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).